Somatic mutation profile of tumor specimen TCGA-2G-AAGI-05A (aliquot TCGA-2G-AAGI-05A-11D-A42Y-10) from TCGA case TCGA-2G-AAGI, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 33.9 years (12,366 days).
Specimen TCGA-2G-AAGI-05A: Sample type: Additional - New Primary; Tissue type: Tumor; Tumor descriptor: New Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59b12ed9-4c29-42e8-92fe-24a9491fbab1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAGI-10A (Blood Derived Normal), aliquot TCGA-2G-AAGI-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71f48602-03d8-4a0c-93e2-fc51b8f838b1

The open-access MAF lists 22 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 2, Intron 1, Nonsense Mutation 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2464A>T p.N822Y | Missense Mutation (SNP) | VAF 15/159 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM087050, COSV55387376, COSV55389464; called by muse, mutect2
- FNBP1L | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 92/825 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1482433450; called by muse, mutect2, varscan2
- HYAL4 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.214); catalogued as rs1219608375; called by muse, mutect2, varscan2
- SEC31B | c.2713C>T p.P905S | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV64845558; called by muse, mutect2, varscan2
- ZFC3H1 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs1380098815; called by muse, mutect2
- ANK3 | c.3966T>A p.D1322E (on ENST00000280772 / NM_001320874.2; = p.D456E on NM_001149.3) | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- BIRC6 | c.1240G>C p.V414L | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CKAP5 | c.1727G>C p.G576A | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2
- GRID1 | c.2538C>A p.C846* | Nonsense Mutation (SNP) | VAF 10/115 reads (9%) | called by muse, mutect2
- KMT2E | c.197A>G p.Y66C | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRP12 | c.928G>T p.G310C | Missense Mutation (SNP) | VAF 39/405 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MMS19 | c.3013G>A p.D1005N | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); called by muse, mutect2
- PLEKHM1 | c.2684C>T p.A895V | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RANBP17 | c.2700G>T p.M900I | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- RYR1 | c.2002G>T p.D668Y | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC37A1 | c.1582G>A p.V528I | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- STAMBPL1 | c.427T>C p.Y143H | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.135); called by muse, mutect2
- RBM10 | c.954G>T p.G318= | Silent (SNP) | VAF 26/130 reads (20%) | called by muse, mutect2, varscan2
- SLC37A3 | c.295C>T p.L99= | Silent (SNP) | VAF 17/204 reads (8%) | catalogued as rs1373074909; called by muse, mutect2
- ACOT6 | c.-25G>T | 5'UTR (SNP) | VAF 16/137 reads (12%) | called by muse, mutect2, varscan2
- CALR | c.*14C>T | 3'UTR (SNP) | VAF 18/187 reads (10%) | catalogued as rs1267251811; called by muse, mutect2, varscan2
- GNPAT | c.1744-50G>C | Intron (SNP) | VAF 29/209 reads (14%) | called by muse, mutect2, varscan2
